Surgical pathology report (de-identified scan), TCGA case TCGA-HU-A4GJ, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site National Cancer Center Korea, specimen TCGA-HU-A4GJ-01A (Primary Tumor).

[page 1 of 3]
GROSS:

Specimen submitted: Distal gastrectomy, unfixed

Measurement: Greater curvature 24.3 cm

Lesser curvature 12.7 cm

Proximal resection margin 13.8 cm

Distal resection margin 5.7 cm

Duodenum 0.7 cm

Tumor location:

Stomach: Lower 1/3 (antrum), lesser curvature

From proximal resection margin - 1.8 cm

From distal resection margin - 1.8 cm

Tumor size: 5.5 x 4.4 cm

Tumor type: AGC (Borrmann type) III

Gross serosal invasion: Puckered

Representative sections are submitted

Blocks

T1-4, tumor and surrounding tissue x 4

A, antral mucosa x 1

B, body mucosa x 1

P, proximal resection margin x 1

D, distal resection margin x 1

LN1-3, superior gastric lymph nodes x 3

LN4-5, inferior gastric lymph nodes x 2

LN6, '1' lymph nodes x 1

LN7, '4b' lymph nodes x 1

LN8, '5' lymph nodes x 1

LN9, '6' lymph nodes x 1

LN10, '7' lymph nodes x 1

LN11, '8' lymph nodes x 1

LN12, '9' lymph nodes x 1

LN13, '11p' lymph nodes x 1

LN14, '12' lymph nodes x 1

1CA-0-3

adenocarcinoma, diffuse type 8/45/3

CQCF Site: Stomach, antrum C16.3

Path: ^{Stomach,} Lesser curvature C16.5 lw 9/27/12

MICROSCOPIC:

Tumor type: Adenocarcinoma - tubular, poorly differentiated

(poorly cohesive carcinoma, by WHO classification)

Depth of tumor invasion:

[page 2 of 3]
T4: Tumor penetration of serosa (visceral peritoneum)
Margins: Proximal resection margin (-)
Distal resection margin (-)
Lauren classification: Diffuse
Ming classification (Growth pattern): Infiltrative
Lymphoid reaction: Present
Lymphovascular invasion: Present
Venous (large vessel) invasion: Absent
Perineural invasion: Present
Lymph node metastasis: Present

DIAGNOSIS:

Stomach, distal gastrectomy:

Adenocarcinoma, poorly differentiated, infiltrating (advanced cancer)

<Addendum>

Final diagnosis: Stomach Adenocarcinoma, Diffuse Type per clarification/update by TSS.

Lymph node, perigastric, distal gastrectomy:

Superior gastric: Metastatic carcinoma, primary in stomach (8/8)

Extranodal tumor extension

Inferior gastric: No tumor present (0/9)

Lymph node, regional, biopsy:

Labeled '1': No tumor present (0/3)

Labeled '4b': No tumor present (0/9)

Labeled '5': Fibrofatty tissue

Labeled '6': No tumor present (0/7)

Labeled '7': No tumor present (0/1)

Labeled '8': No tumor present (0/3)

Labeled '9': Metastatic carcinoma, primary in stomach (2/7)

Labeled '11p': Metastatic carcinoma, primary in stomach (3/3)

Labeled '12': Metastatic carcinoma, primary in stomach (1/1)

Diagnostic Discrepancy		X
HI/PA Discrepancy		X

RM/ 9/29/12

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): Stomach adenocarcinoma

Completed By _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Stomach Adenocarcinoma - Tubular, poorly-differentiated, Diffuse	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF	Stomach Adenocarcinoma, Diffuse Type	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	According to the original pathology report, this tumor is described as a poorly-differentiated tubular adenocarcinoma. In addendum, we clarified the final diagnosis as an stomach adenocarcinoma, diffuse type	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 8454b643-857b-450a-9027-2da1b8384846 (TCGA-HU-A4GJ.F8C3C78C-58AD-4949-B189-DB80638AECCE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).